CCG case CUPP-B5XJ — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/29a6ce6e-d30d-42ac-8f80-508270ab6e1d

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Japan; Year of birth: 1952; Vital status: Alive.

Diagnoses (3)
1. Neuroendocrine carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8246/3; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 67.0 years (24,476 days); Year of diagnosis: 2019; Method of diagnosis: Surgical Resection; AJCC staging edition: 8th; AJCC clinical T: TX; AJCC clinical N: N1; AJCC clinical M: M1; AJCC clinical stage: Stage IV; AJCC pathologic T: TX; AJCC pathologic N: N1; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Liver.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 2; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Residual disease: R0; Timepoint category: First Treatment.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, postoperative; adjuvant Radiation Therapy, NOS, postoperative.
2. Tubular adenocarcinoma: ICD-O-3 morphology code: 8211/3; Tissue or organ of origin: Rectum, NOS; Classification of tumor: Prior primary; Age at diagnosis: 65.6 years (23,948 days); Year of diagnosis: 2017; Days to diagnosis: -528 days (-1.4 years); AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -541 days (-1.5 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Recurrence of the lymph node (histology not recorded by GDC). Age at diagnosis: 67.2 years (24,543 days); Year of diagnosis: 2019; Days to diagnosis: 67 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease; Treatment outcome: Partial Response.

Follow-up (3 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 100; ECOG performance status: 0.
- Day 67 (recurrence): Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 67 days.
- Follow-up contact recording only the day: day 776.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 46 kg; Height: 150 cm; BMI: 20.4.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 20; Tobacco smoking onset year: 1972; Tobacco smoking quit year: 2016.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B5XJ-TTM1-A: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B5XJ-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 32; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
